Somatic mutation profile of tumor specimen MMRF_2380_1_BM_CD138pos (aliquot MMRF_2380_1_BM_CD138pos_T1_KHS5U_L11006) from MMRF case MMRF_2380, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 69.5 years (25,381 days).
Specimen MMRF_2380_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4835714d-74a2-4484-96d9-f861ed62ec9c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2380_1_PB_CD3pos (Blood Derived Normal), aliquot MMRF_2380_1_PB_CD3pos_C2_KHS5U_L11005; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b789811e-486e-43fe-9ea0-5a1764fcf9aa

The open-access MAF lists 103 somatic variants for this specimen: 45 protein-altering or splice-affecting, 17 silent, 41 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, 3'UTR 22, Silent 17, Intron 11, 5'UTR 4, Nonsense Mutation 4, RNA 2, Splice Site 2, 5'Flank 1, 3'Flank 1, Frame Shift Ins 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1900G>A p.D634N (on ENST00000288602 / NM_001374244.1; = p.D594N on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 23/43 reads (53%) | SIFT deleterious (0); PolyPhen benign (0.267); catalogued as rs397516896, COSV56061673, COSV56106240, COSV56184663; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TMPRSS3 | c.647G>A p.R216H | Missense Mutation (SNP) | VAF 83/242 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs137853000, CM054158, CM1513228; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- ANKRD30B | c.2997G>T p.E999D | Missense Mutation (SNP) | VAF 21/55 reads (38%) | SIFT tolerated (0.07); PolyPhen benign (0.101); catalogued as COSV100271489; called by muse, mutect2, varscan2
- CLEC1B | c.44G>A p.R15Q | Missense Mutation (SNP) | VAF 60/366 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.01); catalogued as rs984036218; called by muse, mutect2, varscan2
- CYP46A1 | c.398G>A p.R133H | Missense Mutation (SNP) | VAF 59/155 reads (38%) | SIFT tolerated (0.65); PolyPhen benign (0.047); catalogued as COSV55896830; called by muse, mutect2, varscan2
- DLGAP2 | c.2539C>A p.P847T | Missense Mutation (SNP) | VAF 105/262 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1387305648; called by muse, mutect2, varscan2
- FCRL6 | c.617G>A p.R206H | Missense Mutation (SNP) | VAF 17/34 reads (50%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs77146676; called by muse, mutect2
- GRM3 | c.1025C>T p.P342L | Missense Mutation (SNP) | VAF 93/225 reads (41%) | SIFT tolerated (1); PolyPhen probably damaging (1); catalogued as rs867538929, COSV64480361; called by muse, mutect2, varscan2
- HOXB9 | c.565C>T p.R189C | Missense Mutation (SNP) | VAF 42/198 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs139576077; called by muse, mutect2, varscan2
- IGHV2-70 | c.43T>C p.S15P | Missense Mutation (SNP) | VAF 23/47 reads (49%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.996); catalogued as rs546262332; called by mutect2, varscan2
- IGHV3-30 | c.227A>G p.N76S | Missense Mutation (SNP) | VAF 109/264 reads (41%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.001); catalogued as rs549169420; called by muse, varscan2
- IGLV6-57 | c.202A>G p.I68V | Missense Mutation (SNP) | VAF 118/228 reads (52%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.663); catalogued as rs187919298; called by muse, mutect2
- IL10RB | c.493G>T p.E165* | Nonsense Mutation (SNP) | VAF 274/426 reads (64%) | catalogued as COSV51617647; called by muse, mutect2, varscan2
- KIF16B | c.1696-1G>C p.X566_splice | Splice Site (SNP) | VAF 38/88 reads (43%) | catalogued as COSV100734013; called by muse, mutect2, varscan2
- MIS18BP1 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 72/191 reads (38%) | SIFT tolerated (0.21); PolyPhen benign (0); catalogued as rs774444888, COSV60370659; called by muse, mutect2, varscan2
- MRC2 | c.550G>A p.G184R | Missense Mutation (SNP) | VAF 65/138 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1179405094; called by muse, mutect2, varscan2
- NOL4L | c.539C>T p.T180M | Missense Mutation (SNP) | VAF 26/127 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.998); catalogued as rs770267998; called by muse, mutect2, varscan2
- PCDH12 | c.1762C>A p.L588M | Missense Mutation (SNP) | VAF 99/185 reads (54%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.854); catalogued as COSV51524860; called by muse, mutect2, varscan2
- PKD1 | c.6398T>C p.F2133S | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT tolerated (0.12); PolyPhen benign (0.326); catalogued as rs1269832767; called by muse, mutect2
- PKHD1L1 | c.4444G>A p.G1482R | Missense Mutation (SNP) | VAF 35/249 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs747390847, COSV65739103; called by muse, mutect2, varscan2
- PTTG2 | c.37G>T p.E13* | Nonsense Mutation (SNP) | VAF 72/179 reads (40%) | catalogued as COSV54719834; called by muse, mutect2, varscan2
- SIRPB1 | c.11C>T p.P4L | Missense Mutation (SNP) | VAF 102/183 reads (56%) | SIFT tolerated (0.08); PolyPhen benign (0.111); catalogued as rs1416019007; called by muse, mutect2, varscan2
- STK11 | c.613G>A p.A205T | Missense Mutation (SNP) | VAF 21/96 reads (22%) | SIFT tolerated (0.1); PolyPhen benign (0.084); catalogued as rs730881981, COSV58824180; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TEKT4 | c.373C>T p.R125W | Missense Mutation (SNP) | VAF 59/94 reads (63%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1405580886; called by muse, mutect2, varscan2
- AP3B1 | c.2378A>G p.E793G | Missense Mutation (SNP) | VAF 10/15 reads (67%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.037); called by muse, mutect2, varscan2
- AP3B1 | c.2377G>T p.E793* | Nonsense Mutation (SNP) | VAF 10/15 reads (67%) | called by muse, mutect2, varscan2
- CDH7 | c.246C>G p.I82M | Missense Mutation (SNP) | VAF 5/52 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- CST2 | c.230del p.I77Tfs*5 | Frame Shift Del (DEL) | VAF 142/318 reads (45%) | called by mutect2, varscan2
- DIS3 | c.521T>C p.I174T | Missense Mutation (SNP) | VAF 19/21 reads (90%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); called by muse, mutect2, varscan2
- FAT2 | c.7205A>G p.Q2402R | Missense Mutation (SNP) | VAF 34/76 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.96); called by muse, mutect2, varscan2
- FAT3 | c.1922A>T p.N641I | Missense Mutation (SNP) | VAF 54/123 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.076); called by muse, mutect2, varscan2
- FLG | c.3205A>T p.S1069C | Missense Mutation (SNP) | VAF 178/347 reads (51%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- GNA11 | c.868G>C p.D290H | Missense Mutation (SNP) | VAF 55/216 reads (25%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.92); called by muse, mutect2, varscan2
- HOGA1 | c.184C>A p.H62N | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT tolerated (0.45); PolyPhen benign (0); called by muse, mutect2
- IGLV6-57 | c.203T>G p.I68S | Missense Mutation (SNP) | VAF 118/233 reads (51%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.953); called by muse, mutect2
- KCNMA1 | c.2024T>G p.F675C | Missense Mutation (SNP) | VAF 76/163 reads (47%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- KRT6B | c.1619G>T p.S540I | Missense Mutation (SNP) | VAF 66/146 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.07); called by muse, mutect2, varscan2
- MSX2 | c.621G>T p.K207N | Missense Mutation (SNP) | VAF 65/131 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PRKD1 | c.544C>G p.L182V | Missense Mutation (SNP) | VAF 33/50 reads (66%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.862); called by muse, mutect2, varscan2
- RIPPLY3 | c.267A>C p.Q89H | Missense Mutation (SNP) | VAF 189/284 reads (67%) | SIFT deleterious (0.03); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- TERF2 | c.446dup p.S150Vfs*4 | Frame Shift Ins (INS) | VAF 159/420 reads (38%) | called by mutect2, pindel, varscan2
- TGIF1 | c.625C>T p.Q209* (on ENST00000330513 / NM_001374396.1; = p.Q229* on NM_003244.4) | Nonsense Mutation (SNP) | VAF 54/377 reads (14%) | called by muse, mutect2, varscan2
- USP9X | c.4380+1del p.X1460_splice | Splice Site (DEL) | VAF 12/19 reads (63%) | called by mutect2, pindel, varscan2
- YIF1B | c.169G>A p.G57S (on ENST00000339413 / NM_001039673.3; = p.G42S on NM_001039671.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/73 reads (47%) | SIFT tolerated (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZACN | c.795G>C p.K265N | Missense Mutation (SNP) | VAF 172/387 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- ALMS1 | c.4872C>G p.P1624= | Silent (SNP) | VAF 36/130 reads (28%) | called by muse, mutect2, varscan2
- ANK1 | c.2157T>C p.F719= | Silent (SNP) | VAF 33/72 reads (46%) | called by muse, mutect2, varscan2
- ANKFN1 | c.888C>T p.S296= | Silent (SNP) | VAF 88/223 reads (39%) | catalogued as rs749512570, COSV59452358; called by muse, mutect2, varscan2
- BRINP2 | c.2274G>A p.R758= | Silent (SNP) | VAF 7/141 reads (5%) | catalogued as COSV64175680; called by muse, mutect2
- CDH4 | c.744C>T p.H248= | Silent (SNP) | VAF 33/89 reads (37%) | catalogued as rs753827955, COSV64659999; called by muse, mutect2, varscan2
- IGHV2-70 | c.168C>T p.S56= | Silent (SNP) | VAF 84/170 reads (49%) | catalogued as rs367953381; called by muse, mutect2, varscan2
- IGHV2-70 | c.54A>G p.L18= | Silent (SNP) | VAF 48/108 reads (44%) | catalogued as rs187704106; called by muse, mutect2, varscan2
- IGKJ5 | c.38del p.*14del | Silent (DEL) | VAF 92/214 reads (43%) | called by pindel, varscan2
- IGKJ5 | c.9C>A p.T3= | Silent (SNP) | VAF 128/222 reads (58%) | catalogued as rs375348000; called by muse, varscan2
- LRBA | c.3525A>G p.K1175= | Silent (SNP) | VAF 35/66 reads (53%) | called by muse, mutect2, varscan2
- MATN2 | c.897C>T p.G299= | Silent (SNP) | VAF 136/252 reads (54%) | called by muse, mutect2, varscan2
- MDN1 | c.16110G>A p.K5370= | Silent (SNP) | VAF 42/184 reads (23%) | called by muse, mutect2, varscan2
- MME | c.705T>G p.T235= | Silent (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2, varscan2
- RMDN3 | c.139C>T p.L47= | Silent (SNP) | VAF 85/192 reads (44%) | called by muse, mutect2, varscan2
- SCRT1 | c.229C>T p.L77= | Silent (SNP) | VAF 5/27 reads (19%) | called by muse, mutect2, varscan2
- SLC9A2 | c.273C>T p.A91= | Silent (SNP) | VAF 37/97 reads (38%) | called by muse, mutect2, varscan2
- TGM6 | c.762C>T p.S254= | Silent (SNP) | VAF 17/40 reads (43%) | catalogued as rs764324307, COSV52480734; called by muse, mutect2, varscan2
- AC004593.2 | c.*1010T>G | 3'UTR (SNP) | VAF 28/59 reads (47%) | called by muse, mutect2, varscan2
- AHSA1 | c.844+173G>T | Intron (SNP) | VAF 30/47 reads (64%) | called by muse, mutect2, varscan2
- AL162417.1 | c.397-17159G>A | Intron (SNP) | VAF 49/99 reads (49%) | catalogued as rs546621334; called by muse, mutect2, varscan2
- ALDH1L1 | c.*64G>C | 3'UTR (SNP) | VAF 7/122 reads (6%) | called by muse, mutect2
- ANTXR2 | c.*4227A>C | 3'UTR (SNP) | VAF 18/44 reads (41%) | called by muse, mutect2, varscan2
- AP1G2 | c.-60G>A | 5'UTR (SNP) | VAF 21/50 reads (42%) | catalogued as rs979322732, COSV58113041; called by muse, mutect2, varscan2
- B4GALNT3 | c.708-21C>T | Intron (SNP) | VAF 29/80 reads (36%) | called by muse, mutect2
- C22orf34 | n.2480A>C | RNA (SNP) | VAF 89/104 reads (86%) | called by muse, mutect2, varscan2
- CACUL1 | c.*2465G>A | 3'UTR (SNP) | VAF 13/18 reads (72%) | called by muse, mutect2, varscan2
- CLDN18 | c.*68C>A | 3'UTR (SNP) | VAF 10/13 reads (77%) | called by muse, mutect2, varscan2
- EIF2D | c.-57C>T | 5'UTR (SNP) | VAF 90/178 reads (51%) | called by muse, mutect2, varscan2
- GIT2 | c.1732-170C>T | Intron (SNP) | VAF 28/222 reads (13%) | called by muse, mutect2, varscan2
- GP5 | c.*1631G>C | 3'UTR (SNP) | VAF 7/38 reads (18%) | called by muse, mutect2, varscan2
- GRAMD1B | c.*2584A>C | 3'UTR (SNP) | VAF 44/98 reads (45%) | called by muse, mutect2, varscan2
- IFNAR1 | c.*3290_*3291del | 3'UTR (DEL) | VAF 13/28 reads (46%) | called by mutect2, varscan2
- INHBC | c.*464G>T | 3'UTR (SNP) | VAF 115/282 reads (41%) | called by muse, mutect2, varscan2
- LRRTM4 | c.1551+1112A>T | Intron (SNP) | VAF 42/70 reads (60%) | called by muse, mutect2, varscan2
- MEIS2 | c.*2096G>T | 3'UTR (SNP) | VAF 60/137 reads (44%) | called by muse, mutect2, varscan2
- MICA | c.*309G>A | 3'UTR (SNP) | VAF 17/44 reads (39%) | called by muse, mutect2
- NAA60 | c.-186T>G | 5'UTR (SNP) | VAF 24/58 reads (41%) | called by mutect2, varscan2
- NCOA1 | c.89+163C>T | Intron (SNP) | VAF 8/21 reads (38%) | called by mutect2, varscan2
- NMNAT2 | c.*4203G>A | 3'UTR (SNP) | VAF 20/152 reads (13%) | catalogued as rs200485013; called by muse, mutect2, varscan2
- OPA1 | c.-90G>T | 5'UTR (SNP) | VAF 44/82 reads (54%) | called by muse, mutect2, varscan2
- POGK | c.*1767T>C | 3'UTR (SNP) | VAF 20/118 reads (17%) | called by muse, varscan2
- PRSS30P | n.437C>T | RNA (SNP) | VAF 23/46 reads (50%) | catalogued as rs1012466636; called by muse, mutect2, varscan2
- PRUNE2 | c.756+35125G>T | Intron (SNP) | VAF 99/209 reads (47%) | called by muse, mutect2, varscan2
- PTK2 | c.2710-607del | Intron (DEL) | VAF 13/42 reads (31%) | called by mutect2, pindel, varscan2
- PTPRN2 | c.*977C>T | 3'UTR (SNP) | VAF 53/122 reads (43%) | catalogued as rs903075840; called by muse, mutect2, varscan2
- RAD1 | c.-280-15G>C | Intron (SNP) | VAF 30/74 reads (41%) | called by muse, mutect2
- RASGEF1B | c.*335_*336insAT | 3'UTR (INS) | VAF 27/66 reads (41%) | called by mutect2, pindel, varscan2
- RBBP6 | c.303+90dup | Intron (INS) | VAF 5/18 reads (28%) | called by mutect2, pindel, varscan2
- RNF144A | c.*3992T>C | 3'UTR (SNP) | VAF 8/39 reads (21%) | called by muse, mutect2, varscan2
- SLC26A7 | c.*2014A>C | 3'UTR (SNP) | VAF 48/97 reads (49%) | called by muse, mutect2, varscan2
- SMIM27 | c.*689C>T | 3'UTR (SNP) | VAF 36/81 reads (44%) | catalogued as rs770382214; called by muse, mutect2, varscan2
- SYNCRIP | chr6:85610764 T>G | 3'Flank (SNP) | VAF 6/140 reads (4%) | called by muse, mutect2
- TGFA | c.*2500G>A | 3'UTR (SNP) | VAF 7/27 reads (26%) | called by muse, mutect2, varscan2
- THBD | c.*782A>G | 3'UTR (SNP) | VAF 51/112 reads (46%) | called by muse, mutect2, varscan2
- TMEM108 | c.1451-1974C>T | Intron (SNP) | VAF 40/80 reads (50%) | called by muse, mutect2, varscan2
- USP48 | chr1:21783371 C>G | 5'Flank (SNP) | VAF 52/382 reads (14%) | called by muse, mutect2, varscan2
- YTHDC1 | c.*2293C>T | 3'UTR (SNP) | VAF 20/22 reads (91%) | called by muse, mutect2, varscan2
- ZNF566 | c.*652G>A | 3'UTR (SNP) | VAF 49/111 reads (44%) | catalogued as rs944285857; called by muse, mutect2, varscan2
